Somatic mutation profile of tumor specimen TCGA-B0-4810-01A (aliquot TCGA-B0-4810-01A-01D-1501-10) from TCGA case TCGA-B0-4810, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 47.6 years (17,402 days).
Specimen TCGA-B0-4810-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3ba57db-2767-48dc-af04-b24aa1c86db3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4810-11A (Solid Tissue Normal), aliquot TCGA-B0-4810-11A-02D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e587964-9b3e-4ee7-9786-8ce10ea331e0

The open-access MAF lists 58 somatic variants for this specimen: 48 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 8, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 2, Intron 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 12/273 reads (4%) | hotspot (GDC flag); catalogued as rs1057517809, CS1413088, COSV64290834, COSV64293694, COSV64298429; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AC006059.2 | c.1163C>A p.T388N | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV59606745; called by muse, mutect2, varscan2
- ANKRD50 | c.3577A>G p.R1193G | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.075); catalogued as COSV72385494; called by muse, mutect2, varscan2
- ARHGAP5 | c.488T>G p.I163S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61535323; called by muse, mutect2, varscan2
- ART3 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV61913977; called by muse, mutect2, varscan2
- ATP8A2 | c.896C>A p.S299* | Nonsense Mutation (SNP) | VAF 30/454 reads (7%) | catalogued as COSV54950131; called by muse, mutect2
- BMP2K | c.2227G>T p.D743Y | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs746161635, COSV55009558; called by muse, mutect2, varscan2
- BMX | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.042); catalogued as COSV59591275; called by muse, mutect2, varscan2
- CCDC27 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.242); catalogued as COSV53899968; called by muse, mutect2, varscan2
- CCDC73 | c.2238A>C p.K746N | Missense Mutation (SNP) | VAF 88/400 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV58798099; called by muse, mutect2, varscan2
- COL11A1 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 46/220 reads (21%) | catalogued as COSV62182474; called by muse, mutect2, varscan2
- CYRIA | c.710+1G>A p.X237_splice | Splice Site (SNP) | VAF 148/572 reads (26%) | catalogued as COSV62864419, COSV62865524; called by muse, mutect2, varscan2
- DENND5B | c.3806T>A p.I1269N | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV60902345; called by muse, mutect2, varscan2
- DSCC1 | c.207C>A p.D69E | Missense Mutation (SNP) | VAF 102/432 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV58087016; called by muse, mutect2, varscan2
- FAM9A | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.486); catalogued as rs776487175, COSV66813205; called by muse, mutect2, varscan2
- FHOD1 | c.2815C>A p.R939S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50758747, COSV50760468; called by muse, mutect2, varscan2
- IFNGR1 | c.1470A>T p.*490Cext*11 | Nonstop Mutation (SNP) | VAF 69/201 reads (34%) | catalogued as COSV62991914; called by muse, mutect2, varscan2
- IKZF3 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as rs1463659929, COSV53101981; called by muse, mutect2
- LATS2 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs935412773, COSV101231687; called by mutect2, varscan2
- LRP1B | c.10598G>T p.W3533L | Missense Mutation (SNP) | VAF 126/552 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as rs1243959943, COSV101252326, COSV67214692; called by muse, mutect2, varscan2
- MED4 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1270978819, COSV51639196; called by muse, mutect2, varscan2
- MGAT5 | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 76/322 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV56096168, COSV99924124; called by muse, mutect2, varscan2
- MTOR | c.6628G>C p.A2210P | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.599); catalogued as COSV63870065; called by muse, mutect2, varscan2
- MUC16 | c.6083C>T p.S2028F | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV67459868, COSV67463224; called by muse, mutect2, varscan2
- NEK1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71455933; called by muse, mutect2, varscan2
- NLRP1 | c.1542G>A p.W514* | Nonsense Mutation (SNP) | VAF 28/128 reads (22%) | catalogued as COSV52565475; called by muse, mutect2, varscan2
- NOS1 | c.915C>A p.F305L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV57607703, COSV57611656; called by muse, mutect2, varscan2
- NT5C3A | c.963A>C p.E321D (on ENST00000610140 / NM_001374335.1; = p.E287D on NM_016489.13) | Missense Mutation (SNP) | VAF 152/732 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54237938; called by muse, mutect2
- OR4C6 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 109/463 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV58603728; called by muse, mutect2, varscan2
- PIK3R2 | c.1705C>A p.Q569K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV55847831; called by muse, mutect2, varscan2
- PRICKLE1 | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 109/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61543138, COSV61545370; called by muse, mutect2, varscan2
- RP1 | c.5913C>A p.N1971K | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs754290174, COSV55115958; called by muse, mutect2, varscan2
- RPL18 | c.50A>C p.E17A | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as COSV50031691; called by muse, mutect2
- SHMT1 | c.371A>T p.N124I | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57398743; called by muse, mutect2, varscan2
- SHROOM1 | c.2419G>A p.D807N (on ENST00000378679 / NM_001172700.2; = p.D802N on NM_133456.2) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60581174; called by muse, mutect2, varscan2
- SLC5A11 | c.1097T>C p.L366P | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as COSV61741404; called by muse, mutect2
- TASOR2 | c.4006G>T p.E1336* | Nonsense Mutation (SNP) | VAF 33/167 reads (20%) | catalogued as COSV60167256; called by muse, mutect2, varscan2
- TNFSF14 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV55590476; called by muse, mutect2
- TXNIP | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV65220426; called by muse, mutect2
- U2SURP | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 24/500 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.274); catalogued as COSV67530760; called by muse, mutect2
- VPS13B | c.6181G>T p.D2061Y | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs775482916, COSV62140608; called by muse, mutect2, varscan2
- XKR6 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs1381629350, COSV58655580; called by muse, mutect2, varscan2
- ANAPC4 | c.2019del p.V674Yfs*20 | Frame Shift Del (DEL) | VAF 84/392 reads (21%) | called by mutect2, pindel, varscan2
- GRM2 | c.1766_1767del p.F589Cfs*197 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- KMT2C | c.3256_3259del p.S1086Vfs*31 | Frame Shift Del (DEL) | VAF 47/217 reads (22%) | called by mutect2, pindel, varscan2
- NLGN4X | c.1181A>G p.D394G | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SLC4A1 | c.894del p.Y299Tfs*13 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- VHL | c.369del p.T124Hfs*35 | Frame Shift Del (DEL) | VAF 85/313 reads (27%) | called by mutect2, pindel, varscan2
- AKAP8 | c.1974A>G p.A658= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV54102310; called by muse, mutect2
- CLK1 | c.1047A>G p.E349= | Silent (SNP) | VAF 102/513 reads (20%) | catalogued as COSV58433462; called by muse, mutect2, varscan2
- COMT | c.672A>G p.P224= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV52889741; called by muse, mutect2
- LRP5 | c.4659C>T p.S1553= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs112415702, COSV53715123; called by muse, mutect2, varscan2
- RABGAP1L | c.2037G>A p.P679= | Silent (SNP) | VAF 20/342 reads (6%) | catalogued as rs1225703541, COSV52293022; called by muse, mutect2
- SHROOM1 | c.2418G>T p.L806= (on ENST00000378679 / NM_001172700.2; = p.L801= on NM_133456.2) | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV60581184; called by muse, mutect2, varscan2
- SLC9B2 | c.573T>C p.G191= | Silent (SNP) | VAF 33/213 reads (15%) | catalogued as COSV60019047; called by muse, varscan2
- TCF4 | c.885C>T p.S295= | Silent (SNP) | VAF 92/409 reads (22%) | catalogued as COSV61895833; called by muse, mutect2, varscan2
- AL590867.2 | n.102T>A | RNA (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- NOP58 | c.907+206T>C | Intron (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99970898; called by muse, mutect2
